Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A6E3, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A6E3-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT INTERNAL/EXTERNAL ILIAC, HYPOGASTRIC AND OBTURATOR LYMPH NODES:
Two lymph nodes, no tumor present.
- (B) RIGHT INTERNAL/EXTERNAL ILIAC, HYPOGASTRIC AND OBTURATOR LYMPH NODES:
One lymph node, no tumor present.
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

ICD-O-3
path
Adenocarcinoma NOS 8140/3
ccf
Adenocarcinoma, acinar 8140/3
Subt Prostate NOS C61.9
QW 5/21/13

GROSS DESCRIPTION

- (A) LEFT INTERNAL/EXTERNAL ILIAC, HYPOGASTRIC AND OBTURATOR LYMPH NODES - An irregular fragment of adipose tissue measuring 6.5 x 3.0 x 1.5 cm. The specimen is serially sectioned and two lymph nodes are identified measuring 4.0 x 0.8 x 0.4 and 3.0 x 1.5 x 0.4 cm.
SECTION CODE: A1-A2, one lymph node serially sectioned; A3, A4, one lymph node serially sectioned.
- (B) RIGHT INTERNAL/EXTERNAL ILIAC, HYPOGASTRIC AND OBTURATOR LYMPH NODES - An irregular fragment of adipose tissue measuring 9.0 x 3.0 x 1.0 cm. One lymph node is identified measuring 9.0 x 2.0 x 0.8 cm.
SECTION CODE: One lymph node serially sectioned and entirely submitted in B1-B6.
- (C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

History of prostate cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration

These tests have not been

Released by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

Addendum completed by

DIAGNOSIS

- (C) PROSTATE AND SEMINAL VESICLES:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (3+4). (SEE COMMENT)
TUMOR CONFINED TO THE PROSTATE.
Margins of resection free of tumor.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.
Right and left seminal vesicles, no tumor present.
Segments of right and left vasa deferentia, no tumor present.

Entire report and diagnosis completed by

COMMENT

The prostate gland contains four separate foci of prostatic adenocarcinoma, one in the transition zone and three in the peripheral zone. The dominant tumor focus and the one of the highest histologic grade (Gleason Score 7/3+4) is located in the left transition zone. This tumor focus measures 2.0 x 1.5 cm in the largest cross sectional dimension and it is present in the four cross sections of the prostate, extensively in the apex and focally in the base region. The second largest tumor is located in the right anterolateral peripheral zone. This tumor focus measures 1.5 x 0.3 cm in the largest cross sectional dimension and it is present in the four cross sections of the prostate and focally in the apical region. The third largest tumor focus is located in the left posterolateral peripheral zone. This tumor focus measures 0.6 x 0.1 cm in the largest cross sectional dimension and it is present in one cross section. The fourth tumor focus is located in the right posterolateral peripheral zone. This tumor focus measures 0.1 x < 0.1 cm in the largest cross sectional dimension and it is present in one cross section. All tumor foci are confined to the prostate. The margins of resection are free of tumor.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES - A specimen consisting a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.2 x 2.8 x 3.7 cm, 48 grams, post-fixation), has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. No tumor is palpated externally or observed in the cross sections after fixation.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: C1, C2, right seminal vesicle and segment of right vas deferens from the base towards the tip; C3, C4, left seminal vesicle and segment of left vas deferens from the base towards the tip; C5, prostatic base right border; C6, C7, prostatic base right posterior border; C8-C13, prostatic base central portion; C14, prostatic base left border; C15, C16, prostatic base left posterior border, C17-C20, apex anterior; C21, C22, apex left; C23-C25, apex posterior; C26, apex right; C27-C42, sections of the four cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (C17-26) denotes surfaces but do not represent the true margin of resection.

[page 3 of 3]
[REDACTED]
[REDACTED]
Specimen Date/Time:

SNOMED CODES

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file e38775e2-5566-4cea-a3f2-323d4ad78815 (TCGA-KK-A6E3.4796F9C1-49BD-411E-9D9B-D95001D76F53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).